Surgical pathology report (de-identified scan), TCGA case TCGA-58-8390, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Thoraxklinik at University Hospital Heidelberg, specimen TCGA-58-8390-01A (Primary Tumor).

TSS Name: [REDACTED]

TSS Identifier: [REDACTED]

TSS Unique Patient #: [REDACTED]

Pathology Report-Summary:

Material:

Lung, right, lower lobe: 14.0 x 12.5 x 7.0 cm

Tumor: 5.1 x 4.2 x 3.3 cm

Diagnosis:

Squamous Cell Carcinoma (NOS), partially basaloid

pT2b, pN0 (0/20), pMx, G2

Pathologist: [REDACTED]

Signature:

Date:

Source: NCI Genomic Data Commons file 07ad2a61-e771-43d5-885c-1bfee3352350 (TCGA-58-8390.9C901BB6-5752-4C8A-88F4-689B8CDE19AB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).